Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2A2, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2A2-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex
Location.
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Wide local excision melanoma right lower back - prev excision biopsy 7mm with clear margins. - right axillary dissection for FNA proven metastatic melanoma

FROZEN SECTION REPORT

Fresh tissue was taken for tumour banking (Registrar/

MACROSCOPIC DESCRIPTION

(Di

Two specimens were received.

1. "WIDE LOCAL EXCISION MELANOMA RIGHT LOWER BACK. LONG STITCH LATERAL, SHORT STITCH SUPERIOR". A large ellipse of skin 80 x 40 x 15mm centrally bearing a scarring area 30 x 15mm. There is a long stitch present at one tip and a short stitch present on one side of specimen. Superior half inked blue, inferior half black. Cut surface shows also a small probable dermal abscess 5mm diameter. No residual or recurrent tumour can be identified. One transverse slice from the centre of the specimen divided in two blocks.

2. "RIGHT AXILLARY DISSECTION". A large piece of fatty tissue 120 x 90 x 50, containing multiple enlarged lymph nodes. There is a 20mm diameter whitish nodule with focal pigment on the cut surface present in the centre of the specimen, measuring 40 and 50mm from both periphery and 5mm from the closest resection margin. There are also other smaller lymph nodes identified. In addition there is a triangular piece of skeletal muscle 70 x 50 x 30mm present at one tip of the specimen, with an unremarkable cut surface. The lymph nodes are harvested from the muscle attached end towards the other end, and all embedded in this order.

- A. Three nodes.
- B. Four nodes.
- C-D. Representative section of the largest node.
- E. Four nodes.
- F. Three nodes.
- G. One node bisected.
- H. One node at the muscle attached end trisected.

ICD-0-3

Melanoma, NOS 8720/3

Site: lymph node, axilla C 77.3
lw 6/2/11

IHPAA Discrepancy		3

MICROSCOPIC REPORT

Skin, right lower back

The sections of skin show dermal fibrosis, associated with active chronic inflammation and foreign body histiocytic and giant cell reaction. No evidence of malignancy is seen.

Right axilla, lymph node dissection

Diagnosis: metastatic melanoma

Number of lymph nodes: identified 17; involved by metastatic melanoma: 1

[page 2 of 2]
Requested by:

MRN/Name

Location

Accession:

HISTOPATHOLOGY REPORT

Location of tumour: parenchymal, extensive

Maximal size of largest tumour deposit: ~20mm, accounting for ~90% of the nodal cross-sectional area

Tumour description: pleomorphic, mitotically active, pigment-laden epithelioid cells

Extranodal spread: present (~1mm)

Immunohistochemistry: S-100 positive; HMB-45 positive; Melan-A positive

SUMMARY

Skin, right lower back

Scar and changes in keeping with previous surgery.

No evidence of malignancy.

Right axilla, lymph node dissection

Metastatic melanoma in 1 of 17 lymph nodes.

REPORTED BY: Dr

Source: NCI Genomic Data Commons file 2e1c757f-0dc1-4a6a-bf31-dfc1d071bd3a (TCGA-EE-A2A2.2BADECFD-49E1-416A-8DC4-C3E72FD2E847.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).